Somatic mutation profile of tumor specimen 0DM69Z from CCDI case PBCAEF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.6 years (5,341 days).
Specimen 0DM69Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3733f58-4ea9-4b79-a0b3-fd2e1b2c0fb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM69K (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc792d5d-f12c-4f9c-8fcc-0b1d70143258

The open-access MAF lists 17 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 4, Silent 3, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 542/1120 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- GCC2 | c.3371T>C p.L1124P | Missense Mutation (SNP) | VAF 108/2492 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV59174624; called by muse, mutect2
- KIFAP3 | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 49/1546 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as rs1164863503; called by muse, mutect2
- PBRM1 | c.2779G>T p.E927* | Nonsense Mutation (SNP) | VAF 39/636 reads (6%) | catalogued as COSV56260103; called by muse, mutect2
- CATSPERG | c.2125T>G p.W709G | Missense Mutation (SNP) | VAF 25/488 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LAS1L | c.1442T>A p.L481H | Missense Mutation (SNP) | VAF 31/871 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NPHP1 | c.313del p.R105Efs*4 | Frame Shift Del (DEL) | VAF 498/1511 reads (33%) | called by mutect2, pindel, varscan2
- TAF9 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 58/1512 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.03); called by muse, mutect2
- TECPR1 | c.2686C>A p.P896T | Missense Mutation (SNP) | VAF 204/616 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEX15 | c.4314A>T p.L1438F (on ENST00000256246; = p.L1821F on NM_001350162.2) | Missense Mutation (SNP) | VAF 224/1057 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- FAM160A1 | c.2994G>A p.L998= | Silent (SNP) | VAF 220/803 reads (27%) | called by muse, mutect2, varscan2
- LRP1B | c.11832C>T p.G3944= | Silent (SNP) | VAF 206/2049 reads (10%) | catalogued as rs373732739; called by muse, mutect2
- UBP1 | c.486G>A p.T162= | Silent (SNP) | VAF 94/1256 reads (7%) | catalogued as rs914930006, COSV52147971; called by muse, mutect2
- MCEE | c.40+29C>T | Intron (SNP) | VAF 92/617 reads (15%) | called by muse, mutect2, varscan2
- MEFV | c.1759+21G>T | Intron (SNP) | VAF 37/1171 reads (3%) | called by muse, mutect2
- MPZL2 | c.226-74C>T | Intron (SNP) | VAF 35/133 reads (26%) | catalogued as rs1454773394; called by muse, mutect2, varscan2
- PRKACA | c.47-509C>G | Intron (SNP) | VAF 144/886 reads (16%) | called by muse, mutect2, varscan2
